CCDI case PBBLUX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/279d731e-7668-4f3f-8e27-02e014dd2778

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 1.0 years (373 days).

Biospecimens (3 samples)
- Sample 0DC630: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DC633: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DC639: Tissue type: Tumor; Specimen type: Solid Tissue.
